CPTAC case C3N-02594 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/96d07a2f-3e31-4858-b074-b0ee4794f1ab

Demographics
Sex at birth: female; Race: white; Year of birth: 1952; Vital status: Dead; Days to death: 1,427 days (3.9 years); Year of death: 2021; Country of birth: Poland.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 65.4 years (23,874 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Tumor grade: G2; Residual disease: R1; Days to last known disease status: 1,427 days (3.9 years); Days to last follow up: 1,427 days (3.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 6; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 324, day 665, day 989, day 1,427.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples)
- Sample C3N-02594-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 87 mg.
- Sample C3N-02594-04: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 272 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02594-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
